Gene-level copy-number profile of tumor specimen TCGA-09-2049-01D from TCGA case TCGA-09-2049, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.1 years (23,410 days).
Specimen TCGA-09-2049-01D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.50416b2c-b491-47c0-995e-9236e27c2c3d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-2049-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9443c236-a640-4a88-a315-bae864ee421a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,111; copy number 2: 21,068; copy number 3: 17,805; copy number 4: 10,604; copy number 5: 5,486; copy number 6: 2,051; copy number 7: 939; copy number 8: 698; copy number 9: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-2049-01D-01D-0704-01): tumor purity 0.97, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,830 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,630,335–40,876,670, 139 genes, copy number 5–6 (broad region; genes not listed).
- chr1:143,343,180–241,357,230, 2,386 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:146,587,506–242,160,153, 1,594 genes, copy number 5–7 (broad region; genes not listed).
- chr3:110,527,482–122,025,304, 195 genes, copy number 6 (broad region; genes not listed).
- chr3:137,723,774–143,177,617, 118 genes, copy number 5 (broad region; genes not listed).
- chr3:159,808,416–198,222,513, 681 genes, copy number 5–6 (broad region; genes not listed).
- chr6:10,747,794–10,930,423, 1 gene, copy number 7 (within-gene range 3–7): AL024498.2.
- chr6:10,873,223–34,576,656, 822 genes, copy number 5–7 (broad region; genes not listed).
- chr6:50,897,615–57,646,850, 111 genes, copy number 5 (broad region; genes not listed).
- chr7:119,495,024–159,233,377, 854 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:49,906,863–64,462,926, 201 genes, copy number 5–6 (broad region; genes not listed).
- chr8:138,063,268–145,066,685, 216 genes, copy number 5–6 (broad region; genes not listed).
- chr10:44,712–4,448,692, 71 genes, copy number 5 (broad region; genes not listed).
- chr10:100,105,754–125,896,436, 455 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:59,480,070–59,480,132, 1 gene, copy number 6: RNU7-88P.
- chr14:59,919,713–83,915,377, 496 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:95,990,582–101,933,350, 147 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–6,780,246, 199 genes, copy number 5 (broad region; genes not listed).
- chr20:61,252,261–61,940,617, 1 gene, copy number 5 (within-gene range 4–5): CDH4.
- chr20:61,369,879–64,313,132, 142 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
